Somatic mutation profile of tumor specimen MP2PRT-PAWBKV-TMP1-A (aliquot MP2PRT-PAWBKV-TMP1-A-1-0-D-A80M-36) from MP2PRT case MP2PRT-PAWBKV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.5 years (3,096 days).
Specimen MP2PRT-PAWBKV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79826abc-7231-4c37-bb0f-765f8536e52b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWBKV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWBKV-NB1-A-1-0-D-A80M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55b2c36d-b6af-4f42-8861-d9d3c3cff45f

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAP3 | c.3071C>T p.P1024L | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1367576423; called by muse, mutect2, varscan2
- CACNA1A | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 18/528 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1015798325, COSV64202467; called by muse, mutect2
- NEBL | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 41/387 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs1269179367, COSV65799546; called by muse, mutect2, varscan2
- NLRP4 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 27/616 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs370421219; called by muse, mutect2
- PXDNL | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 140/293 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as rs199619104, COSV62496688; called by muse, mutect2, varscan2
- ARFGEF2 | c.1090G>T p.A364S | Missense Mutation (SNP) | VAF 62/394 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- CLIC1 | c.667dup p.C223Lfs*4 | Frame Shift Ins (INS) | VAF 104/606 reads (17%) | called by mutect2, varscan2
- LAMP2 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 103/693 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- HERC1 | c.11844A>G p.E3948= | Silent (SNP) | VAF 58/447 reads (13%) | called by muse, mutect2, varscan2
- MUC2 | c.2121C>T p.D707= | Silent (SNP) | VAF 25/688 reads (4%) | catalogued as rs563740566; called by muse, mutect2
- NSD2 | c.1213C>T p.L405= | Silent (SNP) | VAF 32/610 reads (5%) | called by muse, mutect2
